Surgical pathology report (de-identified scan), TCGA case TCGA-KJ-A3U4, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Miami, specimen TCGA-KJ-A3U4-01A (Primary Tumor).

[page 1 of 6]
Name:
DOB:
Gender:
MRN:
Location:
Physician:

Case #:
Collected:
Received:
Reported:
Copy To:

Pathologic Interpretation:

A. UTERUS, CERVIX, TUBES AND OVARIES:

Polypoid SEROUS PAPILLARY CARCINOMA of endometrium, 4.0 cm in greatest dimension.

The tumor invades 0.1 cm out of 2 cm of myometrial wall (inner half).
Lymphovascular invasion is present.

Margins are free of tumor.

Leiomyomata uteri (uterus weight 160 grams) up to 1.5 cm.

Simple endometrial hyperplasia.

Lower uterine segment and cervix, free of carcinoma.

Unremarkable, bilateral ovaries and fallopian tubes.

See tumor summary

B. SIGMOID MESENTERY IMPLANT:

SEROUS PAPILLARY CARCINOMA.

C. SIGMOID IMPLANT #2:

SEROUS PAPILLARY CARCINOMA in the muscularis propria.

D. MESENTERY NODULE:

SEROUS PAPILLARY CARCINOMA, in fibrous tissue.

E. SIGMOID LESION:

SEROUS PAPILLARY CARCINOMA in fibroadipose tissue.

F. PELVIC GUTTER LESION:

SEROUS PAPILLARY CARCINOMA in fibroadipose tissue.

G. LEFT PELVIC LYMPH NODE:

Five lymph nodes (0/5), negative for carcinoma.

H. RIGHT PELVIC LYMPH NODE:

Six lymph nodes, (0/6), negative for carcinoma.

I. APPENDIX:

Appendix, no specific pathology change.

J. RIGHT PARA-AORTIC LYMPH NODE:

ICD-O-3
carcinoma, serous, NOS
8441/3
Site: endometrium
C54.1

4-6-12
RP

[page 2 of 6]
One lymph node, (0/1), negative for carcinoma.

K. OMENTUM # 1:

SEROUS PAPILLARY CARCINOMA in adipose tissue.

L. OMENTUM # 2:

Adipose tissue, negative for carcinoma.

M. OMENTUM # 3:

Microscopic focus of serous papillary carcinoma.

N. OMENTUM # 4:

Microscopic focus of serous papillary carcinoma.

O. OMENTUM # 5:

SEROUS PAPILLARY CARCINOMA.

P. BLADDER IMPLANT:

SEROUS PAPILLARY CARCINOMA in fibroadipose tissue.

Q. RIGHT PERICULDE GUTTER IMPLANT:

SEROUS PAPILLARY CARCINOMA in adipose tissue.

Surgical Pathology Cancer Case Summary:

Specimen Type:

Uterine corpus
Cervix
Right ovary
Left ovary
Right fallopian tube
Left fallopian tube
Omentum
Other: Bladder implant's and appendix, sigmoid implants

Procedure:

Simple hysterectomy
Bilateral salpingo-oophorectomy
Peritoneal biopsies
Other: Bladder, appendix, sigmoid implants

Lymph Node Sampling: Performed

Pelvic lymph nodes
Para-aortic lymph nodes

Tumor Site:

Posterior endometrium
Other : Uterine fundus

Tumor Size:

Greatest dimension: 4.0 cm
Additional dimensions: 3.0 x 2.0 cm

Histologic Type: Serous papillary carcinoma

Myometrial Invasion: Present

Depth of invasion: 0.1 cm
Myometrial thickness: 2.1 cm
<50% myometrial invasion

Involvement Of Cervix and Lower Uterine Segment: Not involved

Extent of Involvement of Other Organs:

Right ovary:
Uninvolved
Left ovary:
Uninvolved
Right fallopian tube:
Uninvolved

[page 3 of 6]
Left fallopian tube:
Uninvolved
Omentum:
Involved
Sigmoid implant:
Involved
Bladder wall:
Involved
Peritoneal Ascitic Fluid:
Abnormal cells suspicious
Margins: Uninvolved by invasive carcinoma
Lymph-Vascular Invasion: Present

Pathologic Staging (PTNM [FIGO]): pT1a N0 M1
Primary Tumor (pT):
pT1a [IA]: Tumor limited to endometrium or invades less than one-half of the myometrium

Regional Lymph Nodes (pN):
pN0: No regional lymph node metastasis
Pelvic lymph nodes:
Number of lymph nodes examined: 11
Number lymph nodes involved: 0

Para-aortic lymph nodes:
Number of Lymph Nodes Examined 1
Number of Lymph nodes Involved: 0

Distant Metastasis (pM):
pM1 [IVB]: Distant metastasis ' Specify Site: Omentum
Additional Pathologic Findings:
Simple endometrial hyperplasia without cytologic atypia

Ancillary Studies:

Immunostains to follow.

NOTE: Some immunohistochemical antibodies are analyte specific reagents (ASRs) validated by our laboratory. These ASRs are clinically useful indicators that do not require FDA approval. These clones are used: ID5=ER, PgR 636=PR, A485=HER2, H-11=BCR. All immunohistochemical stains are used with formalin or molecular fixed, paraffin embedded tissue. Detection is by The results are read by a pathologist as positive or negative.

As the attending pathologist, I attest that I: (i) Examined the relevant preparation(s) for the specimen(s); and (ii) Rendered the diagnosis(es).

[Redacted Signature]

Electronically Signed Out By

**Procedures/Addenda
Addendum**

[Redacted Signature]

Addendum Diagnosis

A. UTERUS, CERVIX, TUBES AND OVARIES:

The tumor cells show the following immunoprofile preformed at :

Positive: ER (focally)

[page 4 of 6]
HER-2 (focally positive n)

Negative: PR

Normal expression of MMR proteins (MLH-1, MSH-2, MSH-6, PMS-2) by immunohistochemistry.

Clinical History:

None Provided

Operation Performed

Total abdominal hysterectomy, bilateral salpingo-oophorectomy, pelvic lymph node dissection

Pre Operative Diagnosis:

Endometrial cancer

Specimen(s) Received/Processing Information:**Fee Codes:**

A: UTERUS, CERVIX, TUBES AND OVARIES H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, Est

B: SIGMOID MESENTERY IMPLANT H&E, Initial x 1

C: SIGMOID IMPLANT #2 H&E, Initial x 1, H&E, Initial x 1

D: MESENTERY NODULE H&E, Initial x 1

E: SIGMOID LESION H&E, Initial x 1

F: PELVIC GUTTER LESION H&E, Initial x 1, H&E, Initial x 1

G: LEFT PELVIC LYMPH NODE H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1

H: RIGHT PELVIC LYMPH NODE H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1

I: APPENDIX H&E, Initial x 1

J: RIGHT PARA-AORTIC LYMPH NODE H&E, Initial x 1, H&E, Initial x 1

K: OMENTUM #1 H&E, Initial x 1, H&E, Initial x 1

L: OMENTUM #2 H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1

M: OMENTUM #3 H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1

[page 5 of 6]
N: OMENTUM #4 H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1

O: OMENTUM #5 H&E, Initial x 1, H&E, Initial x 1

P: BLADDER IMPLANT H&E, Initial x 1

Q: RIGHT PERICULDL E GUTTER IMPLANT H&E, Initial x 1

Gross Description:

A. Received fresh labeled "Uterus, cervix, tubes and ovaries" is a hysterectomy weighing 160 grams. The specimen includes an unopened uterus that measures 5.5 x 6.0 x 3.0 cm with attached cervix (3.0 x 3.0 x 2.5 cm), right fallopian tube 7.5 cm in length by 1.0 cm in diameter, right ovary (3.5 x 2.0 x 1.0 cm), left fallopian tube (7.0 cm in length by 1.0 cm in diameter) and left ovary (2.5 x 1.4 x 1.0 cm). The external os is slit-like and measures 0.3 cm in diameter. The endocervical canal 2.8 cm in length) has a tan herring-bone mucosa. The endometrial cavity (4.0 cm from cornu to cornu and 4.4 cm in length) has a tan endometrial lining. There is a 4.0 x 3.0 x 2.0 cm polypoid tan mass that is located on the posterior wall. There appears to be invasion of the underlying mucosa involving the inner half of the myometrium (0.9 out of 2.1 cm). The mass is located 2.8 cm from the lower uterine segment. A 2.0 x 2.0 x 1.0 cm of mass was taken for tissue bank. The myometrium measures 2.1 cm in maximum thickness. Multiple intramural and subserosal white, whorled nodules are present ranging from 1.0 up to 1.5 cm. The endometrial thickness not involved by the tumor is 0.1 cm. The right fallopian tube has multiple paratubal cysts ranging from 0.1 up to 0.4 cm. Fallopian tubes are patent and have fimbriated ends. The right ovary has a multi-nodular white outer surface. Cross section shows a firm, white stroma. The left ovary has a multinodular white outer surface. Cross section reveals a white, firm parenchyma. Sections submitted as follows:

- Cassette #1 Anterior cervix
- Cassette #2 Posterior cervix
- Cassette #3 Anterior lower uterine segment
- Cassette #4 Posterior lower uterine segment
- Cassettes #5&6 Representative section of the tumor in relation with the deepest stromal invasion
- Cassettes #7&8 Representative section of the tumor
- Cassettes #9&10 Representative section of the intramural and serosal myomas
- Cassette #11 Anterior endometrium
- Cassette #12 Posterior endometrium
- Cassette #13 Right fallopian tube and ovary
- Cassette #14 Left fallopian tube and ovary

B. Received in formalin labeled "Sigmoid mesenteric implant" are two fragments. The largest is pale tan and measures 0.4 x 0.3 x 0.3 cm. The smallest is red, hemorrhagic, measuring 0.4 x 0.3 x 0.3 cm. The smaller is red, hemorrhagic and measures 0.3 x 0.2 x 0.2 cm. Submitted in toto in one cassette.

C. Received in formalin labeled "Sigmoid implant #2" are multiple fragments of hemorrhagic tan-brown papillary fibrotic tissue that measure in aggregate 7.0 x 7.0 x 1.5 cm. Representative sections are submitted in two cassettes.

D. Received in formalin labeled "Mesenteric node" are two fragments of tan pink papillary nodule measuring 1.2 x 0.8 x 0.8 cm and the smaller fragment measures 0.7 x 0.5 x 0.2 cm. Submitted in toto in one cassette.

E. Received in formalin labeled "Sigmoid lesion" is a 1.4 x 0.9 x 0.5 cm of yellow, lobulated adipose tissue with a lymph node (0.5 x 0.4 x 0.4 cm). Bisected and submitted in toto in one cassette.

F. Received in formalin labeled "Pelvic gutter lesion" are four white slightly firm nodules ranging from 0.6 up to 2.0 cm. Representative sections of the four nodules are submitted in two cassettes.

G. Received in formalin labeled "Left pelvic lymph node" is an 8.0 x 4.0 x 2.0 cm yellow, lobulated adipose tissue. Four lymph nodes are identified, ranging from 1.0 up to 2.0 x 3.2 cm. Sections submitted as follows:

- Cassette #1 One lymph node bisected in toto
- Cassette #2 Two lymph nodes bisected in toto
- Cassettes #3&4 One lymph node in toto

H. Received in formalin labeled "Right pelvic lymph node" are multiple fragments of yellow, lobulated adipose tissue measuring in aggregate 10.0 x 7.0 x 1.5 cm. Six lymph nodes are identified, ranging from 1.5 to 4.0 cm. Sections submitted as follows:

- Cassette #1 One lymph node bisected in toto

[page 6 of 6]
Cassette #2 One lymph node bisected in toto
Cassette #3 One lymph node bisected in toto
Cassettes #4&5 One lymph node in toto
Cassettes #6-9 One lymph node in toto
Cassette #10 One lymph node in toto

- I. Received in formalin labeled "Appendix" is a tan-pink total appendix measuring 4.0 cm in length by 0.3 cm in greatest diameter with attached adipose tissue (3.8 x 2.0 x 1.0 cm). Representative sections are submitted in one cassette.
- J. Received in formalin labeled "Right para-aortic lymph node" is a 5.0 x 2.0 x 1.0 cm of yellow, lobulated adipose tissue and it has a 3.8 x 1.0 x 0.5 cm tan lymph node. The lymph node is submitted in toto in two cassettes.
- K. Received in formalin labeled "Omentum #1" is a 10.5 x 8.0 x 2.0 cm yellow, lobulated adipose tissue 2.5 x 2.0 x 1.5 cm white nodule is present. Sections submitted as follows:
Cassette #1 Representative section of the nodule
Cassette #2 Representative section of the adipose tissue
- L. Received in formalin labeled "Omentum #2" is a 9.0 x 5.5 x 1.5 cm yellow, lobulated adipose tissue. No masses or lymph nodes are identified. Representative sections are submitted in five cassettes.
- M. Received in formalin labeled "Omentum #3" is a 12.0 x 8.0 x 1.0 cm yellow, lobulated adipose tissue. No lesions or lymph nodes are identified. Representative sections submitted in five cassettes.
- N. Received in formalin labeled "Omentum #4" is a 15.0 x 11.0 x 1.0 cm yellow lobulated adipose tissue. No lesions or lymph nodes are identified. Representative sections submitted in five cassettes.
- O. Received in formalin labeled "Omentum #5" is an 11.0 x 8.0 x 1.5 cm yellow lobulated adipose tissue. One fibrotic irregular nodule is present 0.5 x 0.4 x 0.3 cm. A second nodule is identified, well circumscribed, white and firm "0.6 x 0.4 x 0.3 cm. The two nodules are submitted in toto in two cassettes.
- P. Received in formalin labeled "Bladder implant" is a 2.4 x 2.0 x 1.2 cm of white, pink, soft mass. Cross section reveals a heterogeneous white, hemorrhagic and necrotic soft mass. Representative section of this mass is submitted in one cassette.
- Q. Received in formalin labeled "Right peri-culicle gutter implant" is a 7.0 x 3.2 x 2.5 cm of yellow, lobulated adipose tissue with a white, firm mass (3.4 x 3.0 x 2.0 cm). Cross section reveals a white, hemorrhagic, friable mass. Representative section is submitted in one cassette.

True Malignancy History		/

Source: NCI Genomic Data Commons file 13ee32d4-77dc-40bc-9cdd-5513b54363a6 (TCGA-KJ-A3U4.F0B04416-21FE-4DBC-84BB-7188131399B6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).